Surgical pathology report (de-identified scan), TCGA case TCGA-FF-8047, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site SingHealth, specimen TCGA-FF-8047-01A (Primary Tumor).

	Histopathology Report	Biosis No:	Final
Received Date/Time			Final
Reporting Information	Date/Time : Histopathologist : Laboratory :		Final
Consultant-In-Charge			Final
Submitting Physician			Final
Histopathology Report			Final

DIAGNOSIS

LEFT LEVEL 2 CERVICAL LYMPH NODE; EXCISION:
DIFFUSE LARGE B-CELL LYMPHOMA.

GROSS DESCRIPTION

Received a piece of specimen measuring 2 x 1 x 0.5cm which is trisected. One piece measuring 1 x 0.5 x 0.2cm is partitioned for snap-freezing.

Received subsequently in formalin, labelled with patient's data, and designated "cervical lymph node" are fragments of soft tissue altogether measuring 1.5 x 1.5 x 0.8cm, submitted entirely. (A1 & A2; no reserve)

MICROSCOPIC DESCRIPTION

The nodal architecture is diffusely effaced, with spillover into extranodal adipose tissue, by patternless masses of medium-sized cells with ample, pale eosinophilic cytoplasm and irregular, vesicular nuclei containing dispersed chromatin that allows visualisation of one-to-several nucleoli, accompanied by scattered mitoses and apoptotic debris, the latter within tingible-body macrophages that focally impart a "starry-sky" pattern. No granulomas or metastatic malignancy is seen.

The lymphomatous proliferation is strongly and diffusely positive for pan-B cell marker CD20 and coexpresses late-to-postgerminal centre-associated MUM.1 with germinal centre-associated bcl-6, as well as antiapoptosis protein bcl-2 to a far greater extent than can be accounted for by physiological expression in the small numbers of admixed, CD3-positive, reactive, small T-lymphocytes, while being largely negative for germinal centre-associated antigen CD10, which highlights background stroma, thereby excluding Burkitt lymphoma in conjunction with a variable cell proliferation fraction that falls well short of 100%, culminating around 70-80% by Ki-67 immunolabelling. Immunostaining for Cyclin D1 is negative within the lymphoid proliferation, highlighting only physiological expression in scattered histiocytic and activated endothelial nuclei, excluding a blastoid mantle cell lymphoma. Negativity for terminal deoxynucleotidyl transferase, except in rare haematogones, rules out a precursor lymphoblastic neoplasm in conjunction with the CD10-negativity. CD21-immunoreactive follicular dendritic meshworks are rare, peripheralised and markedly attenuated, in keeping with being overrun rather than supporting a folliculocentric component. External positive controls are in working order.

Pathologist :

(For your attention)

Source: NCI Genomic Data Commons file 5d4a1994-dca5-4a7e-9d6c-28ef8ca6a81c (TCGA-FF-8047.EEA72D00-007D-4B3C-8760-889D859674D0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).